Somatic mutation profile of tumor specimen TCGA-AB-2845-03D (aliquot TCGA-AB-2845-03D-01W-0755-09) from TCGA case TCGA-AB-2845, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.6 years (13,728 days).
Specimen TCGA-AB-2845-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 998a956b-31e0-4de3-8d7e-2a274b772bca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2845-11D (Solid Tissue Normal), aliquot TCGA-AB-2845-11D-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef05bd7-ebde-45fc-8257-0165a0ea2e4c

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.930_931insAAGCAGAACCCG p.T310_Q311insKQNP | In Frame Ins (INS) | VAF 6/11 reads (55%) | hotspot (GDC flag); catalogued as COSV57198265, COSV57199915; called by mutect2, varscan2
